Surgical pathology report (de-identified scan), TCGA case TCGA-D7-8576, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-8576-01A (Primary Tumor).

[page 1 of 2]
Material:

1) Material: stomach, Method of collection: Total organ resection

Histopathological Diagnosis:

Examination performed on

Adenocarcinoma tubulare partim mucocellulare invasivum ventriculi (G3), pT3, pN2.

Tubular and partially mucocellular invasive adenocarcinoma of the stomach

Metastases carcinomatosae in lymphonodis No XV/XV.

Cancer metastases in the lymph nodes No XV/XV.

Macroscopic description:

The specimen consisting of the stomach, after being incised along the greater curvature, sized 18,6x15,4 cm with the omentum sized 26x20cm.

Wall thickening in the pyloric region over the area of 12x1 cm with ulceration of 2.5cm in diameter.

Distance from the proximal end: 4.9cm, from distal end: 0.6cm.

Microscopic description:

Adenocarcinoma tubulare partim mucocellulare invasivum ventriculi (G3). Emboliae carcinomatosae massivae vasorum.

Cancerous proliferation involving the whole thickness of the wall, infiltrates into the peritoneum, and fat tissue of the omentum. (mixed type acc. to Lauren class.).

(Proximal boundary) – free of cancer growth. (Distal boundary) – affected with cancer proliferation. Lymph nodes:

1,2/ (periorificial): metastases carcinomatosae in lymphonodis No (II/II).

3/ (lesser curvature): metastases carcinomatosae in lymphonodis No (IV/IV). Infiltratio carcinomatosa capsulae lymphonodorum et telae adiposae perinodalis.

4/ (greater curvature): metastases carcinomatosae in lymphonodis No (VI/VI). Infiltratio carcinomatosa capsulae lymphonodorum et telae adiposae perinodalis.

6/ (pyloric): metastases carcinomatosae in lymphonodo No (I/I). Infiltratio carcinomatosa capsulae lymphonodi et telae adiposae perinodalis.

9/ (celiac artery): metastases carcinomatosae in lymphonodis No (II/II). Infiltratio carcinomatosae capsulae lymphonodorum et telae adiposae perinodalis.

Assistant:

Pathologist:

[page 2 of 2]
Result of immunohistochemical examination

HER2 protein stained with Ventana's Pathway HER-2/neu (4B5) Rabbit Monoclonal Antibody.

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 349829e1-3caa-4e3a-bed0-b7fc6a345dc5 (TCGA-D7-8576.488DA1FE-E3DB-42BB-AF66-6D6DC5936918.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).